Gene-level copy-number profile of tumor specimen TCGA-UY-A9PD-01A from TCGA case TCGA-UY-A9PD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.9 years (29,565 days).
Specimen TCGA-UY-A9PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.07d20156-d179-4467-849f-739d7881163f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UY-A9PD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0c3d202a-c66b-4685-bbb5-5479f05147ca

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 27; copy number 2: 8,292; copy number 3: 22,712; copy number 4: 19,188; copy number 5: 3,465; copy number 6: 2,992; copy number 7: 1,009; copy number 8: 904; copy number 9: 424; copy number 10: 102; copy number 11: 224; copy number 12: 103; copy number 13: 6; copy number 14: 44; copy number 16: 168; copy number 17: 6; copy number 18: 34; copy number 19: 4; copy number 22: 82; copy number 28: 16; copy number 38: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UY-A9PD-01A-11D-A38F-01): tumor purity 0.63, ploidy 3.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,136 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,474,825–40,072,649, 49 genes, copy number 10–14: LINC01685, HSPA5P1, AL354702.1, RRAGC, AL139260.2, AL139260.1, MYCBP, AL139260.3, GJA9, RHBDL2, RNU6-605P, Y_RNA, EIF1P2, AKIRIN1, NDUFS5, MACF1, RNU6-608P, RNA5SP44, AL442071.2, AL442071.1, HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1.
- chr1:143,343,180–151,146,664, 297 genes, copy number 7–8 (broad region; genes not listed).
- chr1:158,999,968–162,599,842, 163 genes, copy number 7 (broad region; genes not listed).
- chr2:49,918,503–76,208,703, 486 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:76,197,855–76,252,927, 1 gene, copy number 8: AC073091.2.
- chr5:150,601,080–151,812,911, 42 genes, copy number 7 (within-gene range 2–7): SYNPO, AC011383.1, AC008453.2, MYOZ3, AC008453.1, RBM22, DCTN4, SMIM3, IRGM, ZNF300, ZNF300P1, AC022106.1, AC022106.2, GPX3, TNIP1, ANXA6, AC008641.1, PDGFRL2P, CCDC69, GM2A, SLC36A3, SLC36A2, ATP6V1G1P5, AC034205.2, AC034205.1, AC034205.3, SLC36A1, RNA5SP197, FAT2, AC011337.1, MIR6499, AC011374.3, AC011374.1, SPARC, CLMAT3, RN7SKP232, AC011374.2, ATOX1, AC091982.1, RPLP1P6, AC091982.3, G3BP1.
- chr6:16,761,138–30,327,382, 431 genes, copy number 7–38 (within-gene range 6–38) (broad region; genes not listed).
- chr6:55,434,373–57,646,850, 24 genes, copy number 7 (within-gene range 4–7): HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1.
- chr8:37,784,191–53,484,067, 258 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr8:99,013,266–99,877,580, 1 gene, copy number 11 (within-gene range 5–11): VPS13B.
- chr8:99,340,305–102,504,137, 81 genes, copy number 11 (broad region; genes not listed).
- chr13:61,199,798–64,076,044, 29 genes, copy number 7: MIR3169, PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr15:19,878,555–26,970,385, 305 genes, copy number 7–8 (broad region; genes not listed).
- chr15:27,038,978–27,208,635, 2 genes, copy number 7: GABRG3-AS1, AC136896.1.
- chr16:7,726,841–8,849,325, 19 genes, copy number 8 (within-gene range 6–8): AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1.
- chr17:27,666,749–35,009,743, 326 genes, copy number 11–17 (within-gene range 6–17) (broad region; genes not listed).
- chr17:35,377,416–36,017,972, 55 genes, copy number 12: AC060766.3, AC060766.6, AC060766.4, AC060766.7, AC060766.5, AC060766.1, SLFN12, SLFN13, AC015911.4, SLFN12L, AC015911.7, SLFN12L, AC015911.5, E2F3P1, TAF5LP1, AC015911.3, TOMM20P2, AC015911.9, AC015911.2, SLFN14, AC015911.6, AC015911.8, AC015911.1, SNHG30, SNORD7, PEX12, AP2B1, AC004134.1, TAF15, RASL10B, GAS2L2, MMP28, AC006237.1, C17orf50, AC015849.2, AC015849.3, AC015849.4, HEATR9, AC015849.6, AC015849.1, CCL5, 7SK, AC015849.5, LRRC37A9P, RDM1, LYZL6, AC244100.1, CCL16, CCL14, AC244100.2, CCL15-CCL14, CCL15, AC244100.3, AC244100.4, CCL23.
- chr17:37,798,894–38,405,593, 18 genes, copy number 10: AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7.
- chr17:39,023,394–39,564,907, 18 genes, copy number 9 (within-gene range 4–9): AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12.
- chr17:56,471,142–60,170,899, 140 genes, copy number 10–22 (broad region; genes not listed).
- chr17:64,319,415–64,542,461, 10 genes, copy number 13–19: PECAM1, Y_RNA, AC234063.1, MILR1, POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95.
- chr17:65,457,541–65,458,408, 1 gene, copy number 11: LINC02563.
- chr19:51,331,536–54,199,971, 238 genes, copy number 9 (broad region; genes not listed).
- chr19:54,209,092–54,209,418, 1 gene, copy number 9: AC245052.2.
- chr19:54,803,535–56,922,213, 141 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
